Somatic mutation profile of tumor specimen TCGA-CZ-5452-01A (aliquot TCGA-CZ-5452-01A-01D-1501-10) from TCGA case TCGA-CZ-5452, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 69.8 years (25,486 days).
Specimen TCGA-CZ-5452-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18e54421-114a-4c44-85a5-99966617849c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-5452-11A (Solid Tissue Normal), aliquot TCGA-CZ-5452-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1413926e-7869-4ca9-9fdc-041196ba85bd

The open-access MAF lists 31 somatic variants for this specimen: 24 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, Frame Shift Del 4, Nonsense Mutation 3, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP5Z1 | c.1972T>C p.Y658H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV62243432; called by muse, mutect2, varscan2
- BAP1 | c.1220del p.D407Vfs*23 | Frame Shift Del (DEL) | VAF 17/122 reads (14%) | catalogued as COSV56239546; called by mutect2, pindel, varscan2
- BTBD9 | c.1601C>A p.S534Y | Missense Mutation (SNP) | VAF 72/395 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV58420902, COSV58434379; called by muse, mutect2, varscan2
- CEP170 | c.561G>T p.E187D | Missense Mutation (SNP) | VAF 195/648 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV60513551; called by muse, mutect2, varscan2
- FAM71B | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs778853067, COSV57229667; called by muse, mutect2
- GPATCH8 | c.3299G>T p.R1100M | Missense Mutation (SNP) | VAF 53/259 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV59197702; called by muse, mutect2, varscan2
- HEPHL1 | c.2612G>T p.R871I | Missense Mutation (SNP) | VAF 90/545 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59895604; called by muse, mutect2, varscan2
- IQGAP1 | c.3121A>C p.I1041L | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.031); catalogued as COSV51590220; called by muse, mutect2, varscan2
- LAMA2 | c.277C>A p.P93T | Missense Mutation (SNP) | VAF 65/314 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as rs530988751, COSV101370933, COSV70353554; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LIPE | c.1422C>G p.F474L | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV54925045, COSV54926007; called by muse, mutect2, varscan2
- LYST | c.2179C>T p.Q727* | Nonsense Mutation (SNP) | VAF 35/229 reads (15%) | catalogued as COSV67712598; called by muse, mutect2, varscan2
- PCDHGA5 | c.1130G>A p.G377E | Missense Mutation (SNP) | VAF 42/272 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.651); catalogued as COSV53912056; called by muse, mutect2, varscan2
- PI15 | c.280G>T p.D94Y | Missense Mutation (SNP) | VAF 51/289 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52643895; called by muse, mutect2, varscan2
- PSG3 | c.837C>G p.S279R | Missense Mutation (SNP) | VAF 43/303 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.151); catalogued as COSV59506494; called by muse, mutect2, varscan2
- PTOV1 | c.535T>A p.C179S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.477); catalogued as COSV55590096; called by muse, mutect2, varscan2
- RALGAPA1 | c.3256C>T p.Q1086* | Nonsense Mutation (SNP) | VAF 15/90 reads (17%) | catalogued as COSV51894355; called by muse, mutect2, varscan2
- TASOR | c.3204C>A p.N1068K (on ENST00000355628 / NM_001365636.2; = p.N692K on NM_015224.3) | Missense Mutation (SNP) | VAF 41/209 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.036); catalogued as COSV62929383; called by muse, mutect2, varscan2
- TDRD5 | c.2596C>T p.P866S | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV54249035; called by muse, mutect2
- TEX44 | c.393A>C p.K131N | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV58355337; called by muse, mutect2, varscan2
- ZNF543 | c.177C>G p.Y59* | Nonsense Mutation (SNP) | VAF 19/132 reads (14%) | catalogued as COSV58629100; called by muse, mutect2, varscan2
- KITLG | c.92del p.N31Ifs*3 | Frame Shift Del (DEL) | VAF 75/422 reads (18%) | called by mutect2, pindel, varscan2
- RASGRP3 | c.411del p.V138Yfs*70 | Frame Shift Del (DEL) | VAF 74/407 reads (18%) | called by mutect2, pindel, varscan2
- RBM19 | c.2226dup p.E743Rfs*72 | Frame Shift Ins (INS) | VAF 57/314 reads (18%) | called by mutect2, pindel, varscan2
- ZNF701 | c.385del p.Q129Kfs*51 (on ENST00000301093; = p.Q63Kfs*51 on NM_018260.3) | Frame Shift Del (DEL) | VAF 19/142 reads (13%) | called by mutect2, pindel, varscan2
- ALDH1A1 | c.147C>T p.L49= | Silent (SNP) | VAF 104/503 reads (21%) | catalogued as COSV52793729; called by muse, mutect2, varscan2
- C3 | c.1179C>T p.G393= | Silent (SNP) | VAF 13/128 reads (10%) | catalogued as rs760790105, COSV55580096; called by muse, mutect2, varscan2
- NT5C1B | c.984G>A p.E328= (on ENST00000359846 / NM_001199086.2; = p.E268= on NM_033253.4) | Silent (SNP) | VAF 22/138 reads (16%) | catalogued as COSV58398487; called by muse, mutect2, varscan2
- OTC | c.633C>T p.F211= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV50003946; called by muse, mutect2, varscan2
- PTGS1 | c.1305G>T p.G435= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV56295651; called by muse, varscan2
- ZNF160 | c.189G>A p.G63= | Silent (SNP) | VAF 78/400 reads (20%) | catalogued as COSV62000697; called by muse, mutect2, varscan2
- MOCS2 | c.-132C>T | 5'UTR (SNP) | VAF 131/743 reads (18%) | catalogued as COSV63741375; called by muse, mutect2, varscan2
